Somatic mutation profile of tumor specimen TCGA-D1-A101-01A (aliquot TCGA-D1-A101-01A-12D-A10M-09) from TCGA case TCGA-D1-A101, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 60.4 years (22,078 days).
Specimen TCGA-D1-A101-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bd34efa-7648-4cc9-8d20-e55eb484427b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A101-10A (Blood Derived Normal), aliquot TCGA-D1-A101-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d23766f-e939-4579-b778-7cade7f32359

The open-access MAF lists 494 somatic variants for this specimen: 362 protein-altering or splice-affecting, 129 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 246, Silent 129, Frame Shift Del 56, Nonsense Mutation 26, Frame Shift Ins 15, Splice Site 10, Splice Region 4, In Frame Del 3, Translation Start Site 2, RNA 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 42/180 reads (23%) | catalogued as rs137852991, CM003583, COSV55395411; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.1933del p.R645Efs*15 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs397507616; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 57/285 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO15A | c.4240G>A p.E1414K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060499798, CM117960, COSV52751503; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTF1A | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 31/322 reads (10%) | catalogued as rs104894186, CM043069, COSV64735315; ClinVar: pathogenic; called by muse, mutect2
- RNF168 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 68/1008 reads (7%) | catalogued as rs148275050, COSV58839007; ClinVar: likely pathogenic; called by muse, mutect2
- AARS2 | c.1964C>A p.S655Y | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55116867; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | catalogued as rs749943218; called by mutect2, varscan2
- ABR | c.754-2A>G p.X252_splice (on ENST00000302538 / NM_021962.5; = p.X215_splice on NM_001092.5) | Splice Site (SNP) | VAF 30/421 reads (7%) | catalogued as COSV52149846; called by muse, mutect2
- AC098582.1 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs200080956, COSV52018456; called by muse, mutect2, varscan2
- ADAM10 | c.598_600del p.E200del | In Frame Del (DEL) | VAF 58/360 reads (16%) | catalogued as rs1566978707; called by pindel, varscan2
- ADGRV1 | c.9521C>T p.P3174L | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1358804279, COSV67992088; called by muse, mutect2
- ADRA2C | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57467962; called by muse, mutect2
- AGTR2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.326); catalogued as COSV64156862; called by muse, mutect2, varscan2
- AHI1 | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55629521, COSV55632945; called by muse, mutect2
- ANKMY1 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV56038763; called by muse, mutect2, varscan2
- ANKRD12 | c.6068G>T p.W2023L | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50838533; called by muse, mutect2
- ANKRD45 | c.623dup p.N208Kfs*2 | Frame Shift Ins (INS) | VAF 20/115 reads (17%) | catalogued as rs1256946605; called by mutect2, pindel, varscan2
- AP2A1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759541757, COSV62820151; called by muse, mutect2, varscan2
- APBA2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); catalogued as COSV68794051; called by muse, mutect2, varscan2
- APEX1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.653); catalogued as rs778698391, COSV51658052; called by muse, mutect2, varscan2
- ARHGAP21 | c.4831G>A p.V1611M | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs745356491, COSV57606752; called by muse, mutect2, varscan2
- ARHGAP27 | c.2219C>T p.T740I (on ENST00000428638 / NM_001282290.1; = p.T399I on NM_199282.3) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs374182883, COSV65358394; called by muse, mutect2, varscan2
- ASMTL | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 10/336 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV67244789; called by muse, mutect2
- ATN1 | c.764del p.P255Hfs*43 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1555143544, COSV63112070; called by mutect2, pindel
- ATN1 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63110676; called by muse, mutect2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 54/244 reads (22%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP1A4 | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | catalogued as COSV63627873; called by muse, mutect2, varscan2
- AZU1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as rs1051889574, COSV52141505; called by muse, mutect2, varscan2
- BAZ2A | c.2504T>C p.L835P | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51641135; called by muse, mutect2, varscan2
- BICDL2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV54157477; called by muse, mutect2, varscan2
- BMI1 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV64958707, COSV64959466; called by muse, mutect2, varscan2
- BNC1 | c.356T>C p.L119S | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61758630; called by muse, mutect2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs763134487; called by mutect2, varscan2
- BRSK2 | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV100373158, COSV57546928; called by muse, mutect2, varscan2
- BTNL2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs777648549, COSV66631526; called by muse, varscan2
- BUB1 | c.2744A>G p.H915R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241068, COSV57065969; called by muse, mutect2
- CACNA1H | c.6755G>A p.G2252D | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); catalogued as COSV52357021; called by muse, mutect2
- CADPS | c.3022G>A p.V1008I | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.078); catalogued as rs1449775502, COSV51894805; called by muse, mutect2
- CAMTA2 | c.2737C>T p.L913F | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1053449625, COSV52778708, COSV52779880; called by muse, mutect2
- CARD9 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59998540; called by muse, mutect2
- CCBE1 | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 11/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67951028; called by muse, mutect2
- CCDC127 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1000113890, COSV57257710; called by muse, mutect2, varscan2
- CCDC184 | c.190del p.A64Pfs*30 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | catalogued as rs750406248; called by mutect2, pindel, varscan2
- CCN4 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV51534289, COSV51535863; called by muse, mutect2
- CDH17 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs774813679, COSV50336065; called by muse, mutect2, varscan2
- CDKL2 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 15/383 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV56734772; called by muse, mutect2
- CFHR4 | c.188C>T p.S63L (on ENST00000367416 / NM_001201551.2; = p.S64L on NM_006684.5) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV52233349; called by muse, mutect2, varscan2
- CHMP2A | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 26/1029 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV53397886; called by muse, mutect2
- CHRM4 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.153); catalogued as rs750280509, COSV59185864; called by muse, mutect2, varscan2
- CHRNB2 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63809092; called by muse, mutect2
- CMAS | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1352674810, COSV57556216; called by muse, mutect2
- CNOT7 | c.459G>C p.W153C | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63517826, COSV63518163; called by muse, mutect2
- CNTNAP2 | c.2604G>T p.E868D | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV62211003, COSV62232879; called by muse, mutect2, varscan2
- COL22A1 | c.60T>A p.S20R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57352132; called by muse, mutect2
- COL6A3 | c.5656C>T p.R1886C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as CM161508, COSV55102043; called by muse, mutect2, varscan2
- COL6A6 | c.3238G>A p.G1080S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs759591819, COSV62021952; called by muse, mutect2, varscan2
- COX4I1 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 99/511 reads (19%) | catalogued as COSV53666130; called by muse, mutect2, varscan2
- CRYGC | c.184del p.E62Sfs*41 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | catalogued as COSV56408662; called by mutect2, pindel
- CSNK1A1L | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as COSV65790011; called by muse, mutect2
- CTRB2 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57316027; called by muse, mutect2, varscan2
- CXXC1 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53276223; called by muse, mutect2
- CYP4A11 | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs868672389, COSV60224921; called by muse, mutect2, varscan2
- DAO | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.054); catalogued as COSV57323855; called by muse, mutect2
- DCBLD2 | c.2128C>A p.P710T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV54583800; called by muse, mutect2, varscan2
- DDX24 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.014); catalogued as COSV58213396; called by muse, mutect2
- DHX29 | c.2291T>A p.F764Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52420638; called by muse, mutect2, varscan2
- DHX34 | c.2645T>C p.V882A | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV60897259; called by muse, mutect2, varscan2
- DHX9 | c.518A>G p.H173R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62361245; called by muse, mutect2, varscan2
- DMXL1 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373140007; called by mutect2, varscan2
- DNAJC4 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs373704240; called by muse, mutect2, varscan2
- DOCK7 | c.5494-1G>T p.X1832_splice (on ENST00000635253 / NM_001367561.1; = p.X1801_splice on NM_033407.3) | Splice Site (SNP) | VAF 17/148 reads (11%) | catalogued as COSV52012223, COSV52016359; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 76/400 reads (19%) | catalogued as rs748134881; called by mutect2, varscan2
- DUSP16 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 28/122 reads (23%) | catalogued as COSV53806900; called by muse, mutect2, varscan2
- EDNRA | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs905733945, COSV60096295; called by muse, mutect2, varscan2
- EFEMP2 | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1276045574, COSV57261159; called by muse, mutect2
- EIF4ENIF1 | c.745G>T p.G249W | Missense Mutation (SNP) | VAF 17/307 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV57517484; called by muse, mutect2
- EMSY | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58264281; called by muse, mutect2, varscan2
- ENDOV | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60498723; called by muse, mutect2, varscan2
- EPHB6 | c.165+1del | Frame Shift Del (DEL) | VAF 15/162 reads (9%) | catalogued as rs771807343; called by mutect2, pindel
- EPX | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs754444904, COSV56598362; called by muse, mutect2, varscan2
- ERAP1 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV57090382; called by muse, mutect2
- ESYT3 | c.1744C>A p.L582M | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67441790; called by muse, mutect2, varscan2
- ETV1 | c.920T>A p.V307D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54148576; called by muse, mutect2, varscan2
- FAM47B | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs965258921, COSV61453604, COSV61457316; called by muse, mutect2, varscan2
- FAM98C | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV53039492; called by muse, mutect2, varscan2
- FAT1 | c.11050C>T p.Q3684* | Nonsense Mutation (SNP) | VAF 24/164 reads (15%) | catalogued as COSV71675390; called by muse, mutect2, varscan2
- FAT1 | c.9326C>T p.A3109V | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV71675391; called by muse, mutect2, varscan2
- FAT2 | c.10381C>A p.P3461T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55826335; called by muse, mutect2, varscan2
- FAT3 | c.4853C>T p.P1618L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs774849735, COSV53082563; called by muse, mutect2
- FBXO10 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs368929348; called by muse, mutect2, varscan2
- FHOD3 | c.3812G>C p.R1271T (on ENST00000359247 / NM_001281739.3; = p.R1288T on NM_025135.5) | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV57180702; called by muse, mutect2
- FKBP15 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775424290, COSV53038005; called by muse, mutect2, varscan2
- FMR1 | c.1062dup p.H355Tfs*15 | Frame Shift Ins (INS) | VAF 28/184 reads (15%) | catalogued as rs781892436; called by mutect2, varscan2
- FNBP4 | c.3017C>T p.A1006V | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV54094437; called by muse, mutect2, varscan2
- FNIP1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV57199114; called by muse, mutect2, varscan2
- FSIP2 | c.19277A>G p.Y6426C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100555874; called by muse, mutect2, varscan2
- GAA | c.2725G>A p.V909M | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs138407065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRB1 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs999920078, COSV54973905, COSV54977638; called by muse, mutect2, varscan2
- GALNS | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs398123440, CM145588, COSV51939506; called by muse, mutect2, varscan2
- GALR3 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50764306; called by muse, mutect2, varscan2
- GDPD2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV65533236; called by muse, mutect2
- GDPD2 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV65533881; called by muse, mutect2
- GEMIN5 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV53563509; called by muse, mutect2, varscan2
- GGN | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV53058205; called by muse, mutect2, varscan2
- GNAT2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142609327; called by muse, mutect2, varscan2
- GPAT3 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52358807; called by muse, mutect2, varscan2
- GPATCH8 | c.2216G>A p.G739D | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.113); catalogued as COSV59196922; called by muse, mutect2
- GRIA2 | c.2559G>T p.Q853H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.965); catalogued as COSV52411063; called by muse, mutect2
- H2AC1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.578); catalogued as rs551684286, COSV51237913; called by muse, mutect2
- HAUS4 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs148360135; called by muse, mutect2, varscan2
- HCN2 | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs993714420, COSV52117518; called by muse, mutect2, varscan2
- HDDC3 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100376617; called by muse, mutect2
- HECW1 | c.4594C>T p.Q1532* | Nonsense Mutation (SNP) | VAF 8/119 reads (7%) | catalogued as COSV67836838; called by muse, mutect2
- HEG1 | c.2290A>G p.T764A | Missense Mutation (SNP) | VAF 83/477 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs945176768, COSV60764420; called by muse, mutect2, varscan2
- HSD17B10 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs781839633, COSV51448632; called by muse, mutect2, varscan2
- HUWE1 | c.5504G>A p.R1835H | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs372535116, COSV53341877; called by muse, mutect2
- HYAL2 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV51701390; called by muse, mutect2, varscan2
- IL18RAP | c.87del p.K29Nfs*66 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as rs756319084; called by pindel, varscan2
- IL22RA1 | c.1670C>T p.T557I | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV54629794; called by muse, mutect2
- ILKAP | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV54519718; called by muse, mutect2, varscan2
- INPP4A | c.2748del p.H916Qfs*28 (on ENST00000074304 / NM_001134224.1; = p.H877Qfs*25 on NM_001566.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as COSV50784881, COSV50812981; called by mutect2, pindel, varscan2
- INPP4A | c.2813G>A p.R938Q (on ENST00000074304 / NM_001134224.1; = p.R899Q on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs755469992, COSV50813064; called by muse, mutect2, varscan2
- IQSEC2 | c.1688G>A p.R563Q (on ENST00000642864 / NM_001111125.3; = p.R358Q on NM_015075.2) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as rs1556863321, COSV100945027; ClinVar: uncertain significance; called by muse, mutect2
- ITGA2B | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV52234212; called by muse, mutect2
- ITGB2 | c.2312G>T p.W771L (on ENST00000302347; = p.W747L on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV56612310; called by muse, mutect2, varscan2
- KIF2C | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV64765271, COSV64765355; called by muse, mutect2
- KIF4A | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53452286; called by muse, mutect2, varscan2
- KLHDC3 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55065374; called by muse, mutect2
- KLHL38 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs368657213, COSV58088531; called by muse, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs749194179; called by mutect2, pindel
- KMT2A | c.4432C>T p.R1478C | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV63290421; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KMT2B | c.8035C>T p.R2679C | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV53073840; called by muse, mutect2, varscan2
- KRBA1 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.842); catalogued as COSV55443289; called by muse, mutect2, varscan2
- KRT33A | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 68/333 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs911461939, COSV50371815; called by muse, mutect2, varscan2
- LARP1 | c.2483T>C p.L828S (on ENST00000518297 / NM_033551.3; = p.L751S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV60430071; called by muse, mutect2
- LCE1A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/283 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV58727822; called by muse, mutect2
- LIPI | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV60714739; called by muse, mutect2
- LNX2 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV60337604; called by muse, mutect2, varscan2
- LRRC8C | c.2099del p.P700Lfs*35 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as rs1557671997; called by mutect2, pindel, varscan2
- LY96 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs887548267, COSV53024758; called by muse, mutect2, varscan2
- MACF1 | c.451-1G>A p.X151_splice | Splice Site (SNP) | VAF 16/220 reads (7%) | catalogued as COSV57103315, COSV99240068; called by muse, mutect2
- MAD1L1 | c.1468A>G p.S490G | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV56243472; called by muse, mutect2, varscan2
- MAML3 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 21/245 reads (9%) | catalogued as COSV59076979; called by muse, mutect2
- MAPK8 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV64409943, COSV64410515, COSV64410559; called by muse, mutect2, varscan2
- MASP1 | c.2004G>A p.W668* | Nonsense Mutation (SNP) | VAF 18/304 reads (6%) | catalogued as COSV61829421; called by muse, mutect2
- MDN1 | c.12713G>A p.R4238Q | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs771870100, COSV65517464; called by muse, mutect2, varscan2
- MED12L | c.2721-2A>G p.X907_splice | Splice Site (SNP) | VAF 13/109 reads (12%) | catalogued as COSV56390750; called by muse, mutect2, varscan2
- MEGF9 | c.760T>C p.C254R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64235010; called by muse, mutect2, varscan2
- METTL15 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV57722409; called by muse, mutect2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MMS22L | c.278T>C p.F93S | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51524655; called by muse, mutect2, varscan2
- MTOR | c.6167C>T p.A2056V | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.338); catalogued as rs1300900441, COSV63869778; called by muse, mutect2
- MTR | c.3313T>C p.F1105L | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.039); catalogued as COSV63965979; called by muse, mutect2, varscan2
- MTRR | c.211-1G>T p.X71_splice (on ENST00000264668; = p.X44_splice on NM_002454.3 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 18/210 reads (9%) | catalogued as COSV52945940; called by muse, mutect2
- MUC16 | c.14995del p.Q4999Rfs*8 | Frame Shift Del (DEL) | VAF 66/398 reads (17%) | catalogued as rs778508627, COSV99064211; called by mutect2, pindel, varscan2
- MUC5B | c.12178C>A p.Q4060K | Missense Mutation (SNP) | VAF 36/742 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71591376; called by muse, mutect2
- MYH7 | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 80/410 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62522161; called by muse, mutect2, varscan2
- MYO16 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs771164441, COSV51792802; called by muse, mutect2, varscan2
- MYO18B | c.530del p.P177Lfs*55 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs748007891; called by mutect2, pindel
- MYO18B | c.4147C>T p.P1383S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV59143661; called by muse, mutect2, varscan2
- MYO1B | c.2432C>T p.A811V | Missense Mutation (SNP) | VAF 46/343 reads (13%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.935); catalogued as COSV58435915; called by muse, mutect2, varscan2
- MYO5C | c.1331T>C p.V444A | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs1305615669, COSV55910403; called by muse, mutect2, varscan2
- MYO7B | c.4396G>A p.G1466R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs899010523, COSV67348524; called by mutect2, varscan2
- NCOA2 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV51221778; called by muse, mutect2, varscan2
- NCOR1 | c.4436C>T p.T1479I | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV51988414; called by muse, mutect2, varscan2
- NCSTN | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54107390; called by muse, mutect2
- NDUFA1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV101007031, COSV65097690; called by muse, mutect2
- NEBL | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as rs370153729, COSV65800323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK9 | c.2137C>A p.L713M | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV53132836; called by muse, mutect2, varscan2
- NEXN | c.1659+2T>C p.X553_splice | Splice Site (SNP) | VAF 4/56 reads (7%) | catalogued as rs1217727550, COSV53936148; called by muse, mutect2
- NFATC1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV53701562; called by muse, varscan2
- NFIB | c.615A>G p.P205= | Splice Region (SNP) | VAF 10/155 reads (6%) | catalogued as COSV66627602; called by muse, mutect2
- NGFR | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); catalogued as rs888476256; called by muse, mutect2
- NISCH | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.714); catalogued as COSV61901634; called by muse, mutect2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 22/176 reads (13%) | catalogued as rs751187638; called by mutect2, varscan2
- NOL4L | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as COSV58170503; called by muse, mutect2, varscan2
- NOP53 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV54410198; called by muse, mutect2, varscan2
- NOP56 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs781343694, COSV61390516; called by muse, mutect2, varscan2
- NOS1 | c.3784C>T p.R1262* | Nonsense Mutation (SNP) | VAF 50/234 reads (21%) | catalogued as COSV57613454; called by muse, mutect2, varscan2
- NPAT | c.555C>T p.T185= | Splice Region (SNP) | VAF 13/159 reads (8%) | catalogued as COSV53720311; called by muse, mutect2
- NR4A2 | c.325dup p.Q109Pfs*3 | Frame Shift Ins (INS) | VAF 24/186 reads (13%) | catalogued as rs774629025; called by mutect2, varscan2
- NSMF | c.1494A>G p.Q498= (on ENST00000371475 / NM_001130969.3; = p.Q496= on NM_015537.4) | Splice Region (SNP) | VAF 15/141 reads (11%) | catalogued as COSV55812684; called by muse, mutect2
- NXF1 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV53675753; called by muse, mutect2, varscan2
- ODF2 | c.2467C>T p.R823C (on ENST00000434106 / NM_153433.2; = p.R799C on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs368885613; called by muse, mutect2, varscan2
- OIP5 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs777709218, COSV55034196; called by muse, mutect2, varscan2
- OR14A16 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV62927247, COSV62927615; called by muse, mutect2
- OR2AE1 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60390795; called by muse, mutect2, varscan2
- OR2C3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs147306837, COSV63574800; called by muse, mutect2, varscan2
- OR2G6 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV58575414; called by muse, mutect2, varscan2
- OR4D11 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV57586685; called by muse, mutect2
- OR52I1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100331832, COSV56169453; called by muse, mutect2
- OR56A3 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61569780; called by muse, mutect2
- OR5AK2 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV58805065; called by muse, mutect2
- OR5B21 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); catalogued as COSV64482153; called by muse, mutect2, varscan2
- OR6C70 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV59245220; called by muse, mutect2, varscan2
- OVGP1 | c.1188G>A p.W396* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV63859586; called by mutect2, varscan2
- PAPOLB | c.701G>A p.C234Y | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV68202754; called by muse, mutect2
- PARP10 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as rs782696401, COSV57297824, COSV57299489; called by muse, mutect2
- PAXIP1 | c.407G>C p.C136S | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68187187; called by muse, mutect2
- PBLD | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV53266927; called by muse, mutect2, varscan2
- PBRM1 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56259988, COSV56294406; called by muse, mutect2, varscan2
- PCDH15 | c.5161G>C p.D1721H | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious, low confidence (0.02); catalogued as COSV64720126; called by muse, mutect2, varscan2
- PCDHA8 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs201868516, COSV65330790; called by mutect2, varscan2
- PCDHB12 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as COSV53392735, COSV53399515; called by muse, mutect2, varscan2
- PCDHB16 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs1554282093, COSV53368168; called by muse, mutect2, varscan2
- PCDHGA3 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.248); catalogued as COSV53987248, COSV99545440; called by muse, mutect2, varscan2
- PCDHGA3 | c.1162G>T p.G388* | Nonsense Mutation (SNP) | VAF 19/344 reads (6%) | catalogued as COSV54002670; called by muse, mutect2
- PCDHGB2 | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV54002688; called by muse, mutect2, varscan2
- PCGF6 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV61495698; called by muse, mutect2
- PDE8B | c.2062C>T p.H688Y | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53738316; called by muse, mutect2, varscan2
- PDK2 | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50304423; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PIK3R1 | c.1540C>T p.R514C (on ENST00000521381 / NM_181523.3; = p.R244C on NM_181504.4) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV57124746; called by muse, varscan2
- PKNOX1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs765796646, COSV52338633; called by muse, mutect2, varscan2
- PKP4 | c.2901C>G p.N967K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV61579895; called by muse, mutect2, varscan2
- PLB1 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59832525; called by muse, mutect2
- PLCB3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.646); catalogued as rs144191345; called by muse, mutect2, varscan2
- PLXNA4 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.612); catalogued as COSV58131238; called by mutect2, varscan2
- POC1B-GALNT4 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57967412; called by muse, mutect2, varscan2
- POLI | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs950431386, COSV54191009; called by muse, mutect2, varscan2
- POLR2B | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1319666522, COSV58900857; called by muse, mutect2
- PPFIA2 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61046657, COSV61050843; called by muse, mutect2, varscan2
- PPIL4 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 17/323 reads (5%) | catalogued as rs1296278642, COSV53566367, COSV53569053; called by muse, mutect2
- PRDM15 | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54157352; called by muse, mutect2
- PREPL | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs78562665, COSV53218455; called by muse, mutect2
- PREX2 | c.1954G>A p.V652M | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55791550; called by muse, mutect2
- PRKCG | c.1651G>T p.G551* | Nonsense Mutation (SNP) | VAF 32/498 reads (6%) | catalogued as COSV54731097; called by muse, mutect2
- PSG4 | c.430+1G>A p.X144_splice | Splice Site (SNP) | VAF 52/580 reads (9%) | catalogued as rs201083946; called by muse, mutect2
- PTH | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56378783, COSV56379025; called by muse, mutect2, varscan2
- PTPRF | c.2763C>A p.N921K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV63447446; called by muse, mutect2, varscan2
- PTPRH | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV54748393; called by muse, mutect2
- PTPRM | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59874165; called by muse, mutect2, varscan2
- PTPRO | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55518640; called by muse, mutect2, varscan2
- RAD54L2 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1166870408, COSV56580646; called by muse, mutect2
- RARG | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV58432960; called by muse, mutect2, varscan2
- RASSF4 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 46/526 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58488144, COSV58488844; called by muse, mutect2
- RASSF7 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV60348016; called by muse, mutect2
- RCSD1 | c.581A>G p.Q194R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV63260418; called by muse, mutect2, varscan2
- REG1B | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV59307079, COSV59307530; called by muse, mutect2
- REPS1 | c.422del p.K141Rfs*4 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as COSV57808997; called by mutect2, pindel
- RIOX2 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV57724600; called by muse, mutect2
- RNF10 | c.2173G>A p.V725M | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1161295380, COSV58047264; called by muse, mutect2
- RSKR | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 28/145 reads (19%) | catalogued as COSV56383314; called by muse, mutect2, varscan2
- RTF1 | c.1681A>G p.S561G | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV67478668; called by muse, mutect2
- RUVBL2 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.162); catalogued as COSV55486615; called by muse, mutect2, varscan2
- RYR1 | c.5390G>A p.R1797H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); catalogued as COSV100617002, COSV62105705; called by muse, mutect2
- RYR1 | c.9259A>G p.I3087V | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV62105710; called by muse, mutect2, varscan2
- SBF2 | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV56306795; called by muse, mutect2, varscan2
- SCFD2 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66375563; called by muse, mutect2
- SFSWAP | c.1231A>C p.T411P | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.092); catalogued as COSV55524479; called by muse, mutect2, varscan2
- SFTPB | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV60894014; called by muse, mutect2, varscan2
- SGSM1 | c.2884C>T p.R962C (on ENST00000400359 / NM_001039948.4; = p.R901C on NM_133454.3) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63082641; called by muse, mutect2, varscan2
- SIGLEC11 | c.423_424del p.H141Qfs*16 | Frame Shift Del (DEL) | VAF 24/188 reads (13%) | catalogued as rs1159749930; called by mutect2, pindel, varscan2
- SLC16A2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs764282182, COSV52084166; called by muse, mutect2, varscan2
- SLC37A4 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.345); catalogued as COSV58155961; called by muse, mutect2
- SLC38A8 | c.920T>C p.V307A | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1432642309, COSV55308704; called by muse, mutect2
- SLC45A2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554113064, COSV56874201; called by muse, mutect2, varscan2
- SLC7A3 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1238407327, COSV53228822; called by muse, mutect2, varscan2
- SLC7A4 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1407623619, COSV60385415; called by muse, mutect2, varscan2
- SLC7A7 | c.1150T>C p.Y384H | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53537924; called by muse, mutect2, varscan2
- SLITRK1 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1210891744, COSV65674557; called by muse, mutect2
- SLITRK5 | c.2699A>G p.Q900R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV61524965; called by muse, mutect2, varscan2
- SLMAP | c.1366C>T p.R456* (on ENST00000428312 / NM_001377924.1; = p.R518* on NM_007159.5) | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as COSV55851283; called by muse, mutect2
- SMARCAL1 | c.1793A>G p.K598R | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376199515; called by muse, mutect2
- SMC1A | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59131159; called by muse, mutect2, varscan2
- SMG5 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1388963306, COSV62436947; called by muse, mutect2
- SORL1 | c.3143G>A p.S1048N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs148278712; called by muse, mutect2, varscan2
- SPOCK1 | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 17/334 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV56460019; called by muse, mutect2
- STAT6 | c.1607+2T>C p.X536_splice | Splice Site (SNP) | VAF 49/216 reads (23%) | catalogued as rs111299084, COSV55667324; called by muse, mutect2, varscan2
- SULF1 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370846825; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | catalogued as rs747003550; called by mutect2, varscan2
- SUPT5H | c.1658T>C p.L553P | Missense Mutation (SNP) | VAF 74/513 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63241286; called by muse, mutect2, varscan2
- SVEP1 | c.10418G>A p.R3473Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.375); catalogued as rs370881734, COSV52841928; called by muse, mutect2, varscan2
- SYAP1 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV66468519; called by muse, mutect2, varscan2
- SYCP3 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV57149756; called by muse, mutect2
- SYMPK | c.3340G>T p.G1114W | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV55571831, COSV55574221; called by muse, mutect2
- SYT12 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.621); catalogued as COSV67354616; called by muse, mutect2, varscan2
- TBC1D15 | c.409T>C p.S137P | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59851700; called by muse, mutect2
- TBC1D24 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.563); catalogued as rs537705878, COSV53547918; called by muse, mutect2, varscan2
- TBC1D28 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 53/578 reads (9%) | catalogued as rs561645236, COSV100561059; called by muse, varscan2
- TBX2 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV53600460; called by muse, mutect2, varscan2
- TENM2 | c.3619C>T p.Q1207* (on ENST00000518659 / NM_001122679.2; = p.Q975* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as COSV69137694; called by muse, mutect2, varscan2
- THAP12 | c.1498C>A p.L500I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV52610374, COSV52612007; called by muse, mutect2, varscan2
- TMEM67 | c.33G>T p.M11I | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV60042922; called by muse, mutect2, varscan2
- TNRC18 | c.6716G>A p.R2239H | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1389463786, COSV60307904, COSV60308192; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TPP1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.752); catalogued as rs190013230, COSV54994942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAPPC6A | c.355-2A>G p.X119_splice (on ENST00000585934 / NM_001270891.2; = p.X133_splice on NM_024108.3) | Splice Site (SNP) | VAF 29/154 reads (19%) | catalogued as COSV50065414; called by muse, mutect2, varscan2
- TRERF1 | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1323477675, COSV61674042; called by muse, mutect2
- TRIM59 | c.603_604del p.S202Ffs*7 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | catalogued as rs763112993; called by mutect2, varscan2
- TXNRD2 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201943415; ClinVar: uncertain significance; called by muse, mutect2
- TYW5 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200376992; called by muse, mutect2, varscan2
- USP28 | c.535-1G>A p.X179_splice | Splice Site (SNP) | VAF 14/124 reads (11%) | catalogued as rs1006523689, COSV50177286; called by muse, mutect2, varscan2
- USP31 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.963); catalogued as rs370063502, COSV99566204; called by muse, mutect2
- USP47 | c.3259G>A p.A1087T (on ENST00000399455 / NM_001372095.1; = p.A999T on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV59694472; called by muse, mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 20/116 reads (17%) | catalogued as rs754083634; called by mutect2, varscan2
- UTP23 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs779194203, COSV59124852; called by muse, mutect2, varscan2
- VCL | c.2200C>A p.L734M | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.662); catalogued as COSV53012978; called by muse, mutect2
- WDR76 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs202129705, COSV51040344; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WLS | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs764615459, COSV52040347; called by muse, mutect2, varscan2
- WWP1 | c.611G>A p.C204Y | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55362508; called by muse, mutect2
- ZFC3H1 | c.2161G>T p.G721* | Nonsense Mutation (SNP) | VAF 8/155 reads (5%) | catalogued as COSV66434821; called by muse, mutect2
- ZFHX3 | c.4315C>T p.R1439* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | catalogued as COSV51729171; called by muse, mutect2
- ZNF148 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV62306698; called by muse, mutect2, varscan2
- ZNF263 | c.1631G>C p.R544T | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV54597631; called by muse, mutect2, varscan2
- ZNF275 | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.909); catalogued as COSV64705161; called by muse, mutect2, varscan2
- ZNF280B | c.953del p.N318Mfs*5 | Frame Shift Del (DEL) | VAF 40/311 reads (13%) | catalogued as COSV64528720; called by mutect2, pindel, varscan2
- ZNF350 | c.1558G>A p.V520M | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs148220969; called by muse, mutect2, varscan2
- ZNF385D | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV55754230, COSV55770534; called by muse, mutect2, varscan2
- ZNF398 | c.871G>T p.D291Y (on ENST00000475153 / NM_170686.3; = p.D120Y on NM_020781.4) | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as COSV60066221; called by muse, mutect2
- ZNF506 | c.513del p.K171Nfs*6 | Frame Shift Del (DEL) | VAF 42/241 reads (17%) | catalogued as rs1232032560; called by mutect2, pindel, varscan2
- ZNF594 | c.1466A>G p.Q489R | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV68385931; called by muse, mutect2
- ADAM19 | c.168_169insT p.V57Cfs*10 | Frame Shift Ins (INS) | VAF 30/300 reads (10%) | called by mutect2, varscan2
- AP2A1 | c.2551del p.Q851Rfs*5 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- ARID5B | c.1474_1480dup p.K494Rfs*36 | Frame Shift Ins (INS) | VAF 23/153 reads (15%) | called by mutect2, varscan2
- ATF7IP | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | called by mutect2, pindel, varscan2
- CA3 | c.245del p.G82Vfs*53 | Frame Shift Del (DEL) | VAF 15/126 reads (12%) | called by mutect2, pindel, varscan2
- CEP162 | c.1149dup p.S384* | Frame Shift Ins (INS) | VAF 35/245 reads (14%) | called by mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 21/147 reads (14%) | called by mutect2, pindel, varscan2
- CHEK2 | c.1114dup p.Y372Lfs*12 (on ENST00000382580 / NM_001005735.2; = p.Y329Lfs*12 on NM_007194.4) | Frame Shift Ins (INS) | VAF 43/260 reads (17%) | called by mutect2, pindel, varscan2
- CIRBP | c.375del p.N126Tfs*63 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, pindel, varscan2
- COL6A6 | c.2395del p.R799Vfs*10 | Frame Shift Del (DEL) | VAF 22/145 reads (15%) | called by mutect2, pindel, varscan2
- EFNB3 | c.69del p.L24Wfs*35 | Frame Shift Del (DEL) | VAF 32/163 reads (20%) | called by mutect2, pindel, varscan2
- ESRRG | c.1352del p.L451Wfs*10 | Frame Shift Del (DEL) | VAF 19/122 reads (16%) | called by mutect2, pindel, varscan2
- EXOSC9 | c.234del p.F78Lfs*23 | Frame Shift Del (DEL) | VAF 48/264 reads (18%) | called by mutect2, varscan2
- GNAZ | c.612del p.Q205Rfs*29 | Frame Shift Del (DEL) | VAF 35/278 reads (13%) | called by mutect2, pindel, varscan2
- IGHA2 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 29/209 reads (14%) | called by muse, mutect2, varscan2
- KALRN | c.5273dup p.P1760Sfs*9 (on ENST00000360013 / NM_001024660.4; = p.P63Sfs*9 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 7/60 reads (12%) | called by mutect2, pindel
- KCNH1 | c.2192dup p.L731Ffs*25 (on ENST00000271751 / NM_172362.3; = p.L704Ffs*25 on NM_002238.4) | Frame Shift Ins (INS) | VAF 16/159 reads (10%) | called by mutect2, pindel, varscan2
- KIAA2026 | c.4342del p.S1448Vfs*17 | Frame Shift Del (DEL) | VAF 36/206 reads (17%) | called by mutect2, pindel, varscan2
- KIF11 | c.2018del p.K673Rfs*3 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | called by mutect2, pindel, varscan2
- KIF7 | c.1709del p.G570Vfs*29 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- LZTR1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.014); called by muse, mutect2
- MAGED1 | c.1883del p.P628Rfs*18 | Frame Shift Del (DEL) | VAF 22/192 reads (11%) | called by mutect2, pindel
- MAP7D3 | c.922del p.Q308Rfs*2 | Frame Shift Del (DEL) | VAF 21/155 reads (14%) | called by mutect2, pindel, varscan2
- MED12 | c.6309_6311del p.Q2115del | In Frame Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, varscan2
- MYO9B | c.2281del p.R761Vfs*18 | Frame Shift Del (DEL) | VAF 33/172 reads (19%) | called by mutect2, pindel, varscan2
- NRXN3 | c.3019_3020dup p.L1008Sfs*13 (on ENST00000335750 / NM_001330195.2; = p.L635Sfs*13 on NM_004796.6) | Frame Shift Ins (INS) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- PCDHA4 | c.826dup p.D276Gfs*9 | Frame Shift Ins (INS) | VAF 32/157 reads (20%) | called by mutect2, pindel, varscan2
- PGBD2 | c.1061del p.F354Sfs*6 | Frame Shift Del (DEL) | VAF 19/135 reads (14%) | called by mutect2, pindel, varscan2
- PHF23 | c.803del p.G268Vfs*63 | Frame Shift Del (DEL) | VAF 26/133 reads (20%) | called by mutect2, pindel, varscan2
- PIAS3 | c.1259dup p.P421Afs*22 | Frame Shift Ins (INS) | VAF 35/274 reads (13%) | called by mutect2, pindel, varscan2
- POLR2B | c.1955+7dup | Splice Region (INS) | VAF 14/83 reads (17%) | called by mutect2, pindel, varscan2
- PTEN | c.764_766del p.V255del | In Frame Del (DEL) | VAF 29/76 reads (38%) | called by mutect2, pindel, varscan2
- PTPRD | c.180dup p.G61Rfs*10 | Frame Shift Ins (INS) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- SCN7A | c.1122del p.F374Lfs*4 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel, varscan2
- SENP6 | c.3009del p.G1004Efs*11 | Frame Shift Del (DEL) | VAF 16/105 reads (15%) | called by mutect2, pindel, varscan2
- SLIT1 | c.2213G>A p.C738Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNX13 | c.505_508del p.L169Efs*10 | Frame Shift Del (DEL) | VAF 43/236 reads (18%) | called by mutect2, pindel, varscan2
- SPATA1 | c.658del p.S220Vfs*45 | Frame Shift Del (DEL) | VAF 53/255 reads (21%) | called by mutect2, pindel, varscan2
- SPIRE2 | c.808del p.L270Sfs*13 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- SYTL2 | c.2118dup p.Q707Tfs*19 (on ENST00000528231 / NM_001162951.2; = p.Q683Tfs*19 on NM_032943.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 29/214 reads (14%) | called by mutect2, pindel, varscan2
- TOB1 | c.823_826del p.I275Ffs*47 | Frame Shift Del (DEL) | VAF 32/166 reads (19%) | called by pindel, varscan2
- TULP4 | c.3842del p.P1281Qfs*27 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- USP13 | c.353del p.L118* | Frame Shift Del (DEL) | VAF 76/430 reads (18%) | called by mutect2, pindel, varscan2
- ZNF16 | c.66del p.W23Gfs*9 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- ZNF668 | c.1726del p.H576Ifs*7 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- ABCC8 | c.2349G>T p.V783= | Silent (SNP) | VAF 12/235 reads (5%) | catalogued as COSV56855222; called by muse, mutect2
- ADCY5 | c.2298G>A p.A766= | Silent (SNP) | VAF 37/210 reads (18%) | catalogued as rs761878371, COSV59201823, COSV59202184; called by muse, mutect2, varscan2
- AGO2 | c.2559G>A p.L853= | Silent (SNP) | VAF 39/260 reads (15%) | catalogued as COSV55050764; called by muse, mutect2, varscan2
- AHNAK | c.3723A>C p.P1241= | Silent (SNP) | VAF 51/542 reads (9%) | catalogued as COSV57224696; called by muse, mutect2
- AKAP12 | c.168A>G p.L56= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs763642797, COSV53569667; called by muse, mutect2, varscan2
- ANKLE2 | c.864G>A p.S288= | Silent (SNP) | VAF 48/722 reads (7%) | catalogued as rs759360832, COSV100514342, COSV61710945; called by muse, mutect2
- ANKRD17 | c.5025G>A p.L1675= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as COSV58225499; called by muse, mutect2
- ANKRD6 | c.129G>A p.R43= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV60234782; called by muse, mutect2
- ANPEP | c.45G>T p.G15= | Silent (SNP) | VAF 47/213 reads (22%) | catalogued as COSV55593667; called by muse, mutect2, varscan2
- APOBR | c.198C>T p.D66= | Silent (SNP) | VAF 14/338 reads (4%) | catalogued as COSV60492925; called by muse, mutect2
- ARHGEF40 | c.2151G>A p.K717= | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as COSV53882933; called by muse, mutect2
- ARSH | c.1206T>C p.I402= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as COSV66963630; called by muse, mutect2
- ARSI | c.1102C>T p.L368= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV60818091; called by muse, mutect2, varscan2
- ARSL | c.1494C>T p.C498= | Silent (SNP) | VAF 28/370 reads (8%) | catalogued as COSV66965627; called by muse, mutect2
- BAHD1 | c.1884C>G p.V628= | Silent (SNP) | VAF 11/210 reads (5%) | catalogued as COSV69084396; called by muse, mutect2
- BANP | c.1260C>T p.H420= (on ENST00000286122; = p.H392= on NM_017869.4) | Silent (SNP) | VAF 33/258 reads (13%) | catalogued as rs755258976, COSV53741136; called by muse, mutect2, varscan2
- BAX | c.442C>T p.L148= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV53171343; called by muse, mutect2, varscan2
- BFSP2 | c.1137G>A p.A379= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV56587387; called by muse, mutect2, varscan2
- C16orf86 | c.801A>G p.G267= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV54752967; called by muse, mutect2, varscan2
- C19orf12 | c.204C>T p.V68= (on ENST00000392278 / NM_001031726.3; = p.V57= on NM_031448.6) | Silent (SNP) | VAF 46/173 reads (27%) | catalogued as rs372589316; called by muse, mutect2, varscan2
- CABLES2 | c.729G>A p.A243= | Silent (SNP) | VAF 21/178 reads (12%) | catalogued as rs764272567, COSV54157888; called by muse, mutect2, varscan2
- CACUL1 | c.528G>A p.S176= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs769837833, COSV60994205, COSV60996122; called by muse, mutect2
- CASZ1 | c.747C>T p.G249= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV59739485; called by muse, mutect2
- CAT | c.822C>T p.Y274= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as COSV53812453; called by muse, mutect2, varscan2
- CCDC74A | c.603C>A p.S201= | Silent (SNP) | VAF 44/464 reads (9%) | catalogued as COSV54608630; called by muse, mutect2
- CCDC74B | c.603C>A p.P201= | Silent (SNP) | VAF 26/346 reads (8%) | catalogued as COSV60101027; called by muse, mutect2
- CCDC85A | c.666G>A p.P222= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1326091665, COSV68147665; called by muse, mutect2, varscan2
- CDH23 | c.7785C>T p.T2595= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV56480998; called by muse, mutect2, varscan2
- CDR1 | c.36C>T p.D12= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as rs777604320, COSV65164577; called by muse, mutect2, varscan2
- CELF4 | c.177G>A p.G59= | Silent (SNP) | VAF 12/260 reads (5%) | catalogued as COSV58461845; called by muse, mutect2
- CELSR1 | c.3681C>T p.F1227= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs376620789; called by muse, mutect2, varscan2
- CNGB3 | c.528C>T p.S176= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as rs765444763, COSV60686301; called by muse, mutect2, varscan2
- CNTNAP1 | c.2922C>T p.C974= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as rs754491731, COSV52852995, COSV52853762; called by muse, mutect2, varscan2
- COL18A1 | c.3729T>C p.D1243= (on ENST00000359759 / NM_130444.3; = p.D1008= on NM_030582.4) | Silent (SNP) | VAF 37/242 reads (15%) | catalogued as COSV60592110; called by muse, mutect2, varscan2
- CSE1L | c.2811C>T p.T937= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs753453001, COSV53704084; called by muse, mutect2, varscan2
- CTC1 | c.2682C>A p.S894= | Silent (SNP) | VAF 13/275 reads (5%) | catalogued as COSV59854608; called by muse, mutect2
- CYP2A13 | c.699A>G p.P233= | Silent (SNP) | VAF 68/442 reads (15%) | catalogued as COSV57839426; called by muse, mutect2, varscan2
- DCAF8L1 | c.78G>A p.Q26= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV71595445; called by muse, mutect2
- DHRS7B | c.633G>A p.K211= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as COSV60888351; called by muse, mutect2
- DHX36 | c.1176G>C p.P392= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV57675750; called by muse, mutect2, varscan2
- DNAI4 | c.1771C>T p.L591= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV64023070; called by muse, mutect2
- ELOA | c.435G>A p.T145= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs1448680463, COSV69310945; called by muse, mutect2, varscan2
- EPHB2 | c.3051A>G p.G1017= | Silent (SNP) | VAF 68/326 reads (21%) | catalogued as rs776846376, COSV65864984; called by mutect2, varscan2
- FAM50B | c.396C>T p.D132= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs926532304, COSV66655086; called by muse, mutect2, varscan2
- FARP1 | c.2946G>A p.S982= | Silent (SNP) | VAF 30/256 reads (12%) | catalogued as rs766113572, COSV60344159; called by muse, mutect2, varscan2
- FCN1 | c.888C>A p.P296= | Silent (SNP) | VAF 22/329 reads (7%) | catalogued as COSV65662738; called by muse, mutect2
- GHRHR | c.714A>G p.S238= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV58197644; called by muse, mutect2, varscan2
- GNPTAB | c.249T>C p.N83= | Silent (SNP) | VAF 48/244 reads (20%) | catalogued as COSV71820791; called by muse, mutect2, varscan2
- GOLGA6A | c.906T>C p.D302= | Silent (SNP) | VAF 30/230 reads (13%) | catalogued as rs1334915120, COSV99297315; called by muse, mutect2, varscan2
- GPR37L1 | c.885C>A p.P295= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs144820477, COSV66162663; called by muse, mutect2, varscan2
- HDC | c.978G>A p.Q326= | Silent (SNP) | VAF 22/247 reads (9%) | catalogued as COSV51076845; called by muse, mutect2
- HIF1A | c.1857C>T p.A619= | Silent (SNP) | VAF 17/164 reads (10%) | catalogued as COSV60190740; called by muse, mutect2, varscan2
- HIVEP1 | c.7371G>T p.V2457= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV65103963; called by muse, mutect2, varscan2
- IFT52 | c.789G>A p.L263= | Silent (SNP) | VAF 14/282 reads (5%) | catalogued as COSV65975724; called by muse, mutect2
- IGSF10 | c.474G>A p.V158= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV56789800; called by muse, mutect2, varscan2
- IL22 | c.63C>T p.L21= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV60160556; called by muse, mutect2
- IPO9 | c.1173T>C p.D391= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV64235049; called by muse, mutect2
- ITGA3 | c.2263C>T p.L755= | Silent (SNP) | VAF 19/300 reads (6%) | catalogued as COSV50329170; called by muse, mutect2
- ITGA7 | c.1830G>A p.Q610= (on ENST00000555728; = p.Q566= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV57698959; called by muse, mutect2, varscan2
- KCNH8 | c.2295G>A p.S765= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs368682045; called by muse, mutect2, varscan2
- KIAA0753 | c.582T>C p.H194= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as COSV63818371; called by muse, mutect2
- KMT2C | c.11979T>C p.G3993= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV51480568; called by muse, mutect2, varscan2
- KRT24 | c.354C>T p.G118= | Silent (SNP) | VAF 27/466 reads (6%) | catalogued as COSV52881367; called by muse, mutect2
- LDOC1 | c.156C>A p.P52= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV65159556; called by muse, mutect2, varscan2
- LIG1 | c.1479G>A p.K493= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV54394591; called by muse, mutect2, varscan2
- LRRC30 | c.708G>A p.L236= | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2
- MACROD2 | c.330C>T p.G110= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV54027787; called by muse, mutect2
- MBTPS2 | c.363C>T p.S121= | Silent (SNP) | VAF 34/372 reads (9%) | catalogued as rs1244066213, COSV63412148; called by muse, mutect2
- MIB2 | c.828G>A p.A276= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs770239633, COSV61756975; called by muse, mutect2, varscan2
- MPHOSPH10 | c.333A>G p.E111= | Silent (SNP) | VAF 10/328 reads (3%) | catalogued as rs1222221697, COSV54906709; called by muse, mutect2
- MSLNL | c.1119G>A p.L373= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV53504948; called by muse, mutect2, varscan2
- NACC1 | c.867C>T p.G289= | Silent (SNP) | VAF 66/293 reads (23%) | catalogued as rs761461593, COSV52835442; called by muse, mutect2, varscan2
- NOD2 | c.1501C>T p.L501= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV56053662; called by muse, mutect2
- NPR1 | c.2535T>C p.A845= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV64117943; called by muse, mutect2, varscan2
- NUP214 | c.2694G>A p.S898= | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as rs751690028, COSV63911922; called by muse, mutect2, varscan2
- OR4C15 | c.309C>T p.S103= (on ENST00000314644; = p.S49= on NM_001001920.2) | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs1017684499, COSV58952596, COSV58954638; called by muse, mutect2
- OR8S1 | c.1017G>A p.T339= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1379039229, COSV59600462; called by muse, mutect2
- PAPPA | c.2940C>A p.S980= | Silent (SNP) | VAF 37/276 reads (13%) | catalogued as COSV60289295; called by muse, mutect2, varscan2
- PCDH17 | c.1686C>T p.H562= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV64977278; called by muse, mutect2
- PCDHA11 | c.1230C>T p.S410= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as rs564033882, COSV56532888; called by muse, mutect2
- PCDHB6 | c.1215C>T p.G405= | Silent (SNP) | VAF 58/351 reads (17%) | catalogued as COSV50714094; called by muse, mutect2, varscan2
- PCDHGA1 | c.2190C>T p.G730= | Silent (SNP) | VAF 28/300 reads (9%) | catalogued as COSV65294725; called by muse, mutect2
- PCDHGA8 | c.489C>T p.G163= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV53988163; called by muse, mutect2, varscan2
- PCLO | c.3729T>C p.P1243= | Silent (SNP) | VAF 14/313 reads (4%) | catalogued as COSV61655760; called by muse, mutect2
- PITPNM3 | c.2526G>A p.T842= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs982152571, COSV52598511; called by muse, mutect2, varscan2
- PKD1 | c.12222G>A p.L4074= (on ENST00000262304 / NM_001009944.3; = p.L4073= on NM_000296.4) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as CD1313933, COSV51922245; called by mutect2, varscan2
- PLEKHA5 | c.1080T>C p.P360= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV54708790; called by muse, mutect2, varscan2
- PML | c.690C>T p.S230= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV51451559; called by muse, mutect2, varscan2
- POM121 | c.1203C>T p.Y401= (on ENST00000434423; = p.Y136= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/256 reads (21%) | catalogued as rs782014645, COSV57516621; called by muse, mutect2, varscan2
- PPM1E | c.1689G>A p.V563= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV57578020; called by muse, mutect2
- PPP3CA | c.126T>C p.R42= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV59919544, COSV59928802; called by muse, mutect2
- PTPN11 | c.879C>T p.H293= | Silent (SNP) | VAF 31/386 reads (8%) | catalogued as rs117730996, COSV61006650; ClinVar: benign / likely benign; called by muse, mutect2
- PTPRM | c.3378C>T p.C1126= | Silent (SNP) | VAF 24/221 reads (11%) | catalogued as rs775794517, COSV59874170; called by muse, mutect2, varscan2
- RCN1 | c.303T>C p.T101= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as COSV50014972; called by muse, mutect2, varscan2
- RND3 | c.126C>G p.V42= | Silent (SNP) | VAF 35/204 reads (17%) | catalogued as COSV55725530; called by muse, mutect2, varscan2
- ROBO3 | c.1410G>A p.L470= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs763789964, COSV67302114; called by muse, mutect2, varscan2
- RWDD2B | c.564G>A p.T188= | Silent (SNP) | VAF 53/278 reads (19%) | catalogued as rs760441462, COSV54502074; called by muse, mutect2, varscan2
- S100B | c.198C>T p.D66= | Silent (SNP) | VAF 18/455 reads (4%) | catalogued as rs1386130740, COSV52453328; called by muse, mutect2
- SAMD4B | c.1932G>A p.P644= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as rs572937625, COSV55395620; called by muse, mutect2, varscan2
- SEC31B | c.753G>A p.S251= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs776800579, COSV64825061; called by muse, mutect2, varscan2
- SEC63 | c.1665C>T p.V555= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as rs941366235, COSV64599495; called by muse, mutect2
- SEMA5A | c.2136C>A p.P712= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV66801977; called by muse, mutect2
- SEMA7A | c.1713C>T p.R571= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as COSV56091641; called by muse, mutect2
- SEPTIN12 | c.837G>A p.A279= | Silent (SNP) | VAF 23/242 reads (10%) | catalogued as rs148619854; called by muse, mutect2
- SETD5 | c.1128G>A p.V376= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as COSV56715518; called by muse, mutect2, varscan2
- SKOR1 | c.693C>T p.D231= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as COSV58248905; called by muse, mutect2
- SLC1A6 | c.741G>A p.L247= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs1319477909, COSV55672673; called by muse, mutect2, varscan2
- SLC35E3 | c.531G>A p.Q177= | Silent (SNP) | VAF 43/444 reads (10%) | catalogued as COSV60118245; called by muse, mutect2
- SLC9B2 | c.1422A>G p.T474= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV60021190; called by muse, mutect2, varscan2
- SORCS2 | c.567G>A p.T189= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as rs575501301, COSV61164003; called by muse, mutect2, varscan2
- SSH1 | c.1200G>T p.S400= | Silent (SNP) | VAF 9/137 reads (7%) | catalogued as COSV58458789; called by muse, mutect2
- STXBP5 | c.1989G>A p.L663= | Silent (SNP) | VAF 39/486 reads (8%) | catalogued as COSV51656010; called by muse, mutect2
- TAF6L | c.708C>T p.R236= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as COSV53670321; called by muse, mutect2
- TGM1 | c.396C>T p.D132= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as rs376590179; ClinVar: likely benign; called by muse, mutect2, varscan2
- TIE1 | c.1233C>T p.F411= | Silent (SNP) | VAF 60/315 reads (19%) | catalogued as rs146776938; called by muse, mutect2, varscan2
- TLE4 | c.1176C>A p.A392= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV54638307; called by muse, mutect2, varscan2
- TLN1 | c.5179C>T p.L1727= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as COSV59210375; called by muse, mutect2
- TMUB2 | c.246G>A p.G82= (on ENST00000538716 / NM_001353177.2; = p.G62= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 13/199 reads (7%) | catalogued as rs1164729271, COSV60229601; called by muse, mutect2
- TRAPPC3 | c.474C>T p.D158= | Silent (SNP) | VAF 38/250 reads (15%) | catalogued as rs765168012, COSV64264218; called by muse, mutect2, varscan2
- TRPS1 | c.702C>T p.N234= (on ENST00000220888 / NM_001330599.2; = p.N247= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs577432775, COSV104378173, COSV55242514; called by muse, mutect2, varscan2
- TSHZ3 | c.465C>T p.S155= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as COSV53665621; called by muse, mutect2
- TTC3 | c.1554C>T p.N518= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs200220978; called by muse, mutect2, varscan2
- UBN1 | c.2028G>A p.V676= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs199741494, COSV52171048; called by mutect2, varscan2
- UBR3 | c.4683G>A p.K1561= | Silent (SNP) | VAF 7/155 reads (5%) | catalogued as COSV55856734; called by muse, mutect2
- USP39 | c.345G>A p.V115= | Silent (SNP) | VAF 52/393 reads (13%) | catalogued as COSV60382900; called by muse, mutect2, varscan2
- UST | c.549C>T p.V183= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as COSV66549239; called by muse, mutect2
- VAC14 | c.1620C>T p.S540= | Silent (SNP) | VAF 51/300 reads (17%) | catalogued as rs762141124, COSV55756384; called by muse, mutect2, varscan2
- WWC1 | c.387G>A p.Q129= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV54656373; called by muse, mutect2, varscan2
- ZNF569 | c.94C>T p.L32= | Silent (SNP) | VAF 9/228 reads (4%) | catalogued as COSV57597944; called by muse, mutect2
- CCNQP1 | n.28C>T | RNA (SNP) | VAF 65/343 reads (19%) | catalogued as rs568832052; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6048864 C>T | 3'Flank (SNP) | VAF 11/334 reads (3%) | catalogued as COSV51536589, COSV51540996; called by muse, mutect2
- TOR2A | c.593+49G>T | Intron (SNP) | VAF 13/56 reads (23%) | catalogued as COSV59127869; called by muse, mutect2, varscan2
